Somatic mutation profile of tumor specimen TCGA-HT-7604-01A (aliquot TCGA-HT-7604-01A-11D-2086-08) from TCGA case TCGA-HT-7604, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 50.5 years (18,443 days).
Specimen TCGA-HT-7604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d51a1630-7906-4f6b-889f-f7221f92a6b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7604-10A (Blood Derived Normal), aliquot TCGA-HT-7604-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e27c648c-09b8-41fc-b360-6af0c4386aac

The open-access MAF lists 47 somatic variants for this specimen: 35 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Silent 12, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 61/114 reads (54%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 44/109 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 26/72 reads (36%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100735837, COSV62931685; called by muse, mutect2, varscan2
- ABCB1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs761584848, COSV55950092; called by muse, mutect2
- ACAD9 | c.1493C>G p.A498G | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV58309149; called by muse, mutect2, varscan2
- APOB | c.9185T>G p.L3062* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV51945601; called by muse, mutect2
- ATRX | c.3003del p.V1002* | Frame Shift Del (DEL) | VAF 43/64 reads (67%) | catalogued as COSV64877278; called by mutect2, pindel, varscan2
- C11orf65 | c.779A>G p.N260S | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.022); catalogued as COSV67598178; called by muse, mutect2
- C20orf194 | c.368A>G p.H123R | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs959564588, COSV52700285; called by muse, mutect2, varscan2
- C6orf118 | c.415T>C p.S139P | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as COSV57817386; called by muse, mutect2, varscan2
- CFAP54 | c.8018C>T p.S2673L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as rs771701442, COSV61572169, COSV61572440; called by muse, mutect2, varscan2
- DOCK4 | c.563A>T p.H188L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV70324313; called by muse, mutect2, varscan2
- GPBP1 | c.1033C>T p.R345* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as rs1269913815, COSV53313584; called by muse, mutect2, varscan2
- INKA2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.107); catalogued as rs142952172; called by muse, mutect2, varscan2
- ITPR2 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476004438, COSV54385905; called by muse, mutect2, varscan2
- LIPG | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54297279; called by muse, mutect2, varscan2
- LRP2 | c.10930A>G p.N3644D | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1423898945, COSV55565938; called by muse, mutect2, varscan2
- MUC16 | c.24724A>G p.T8242A | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.041); catalogued as rs1236053637, COSV67481515; called by muse, mutect2, varscan2
- NNMT | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 97/179 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as COSV55474533; called by muse, mutect2, varscan2
- OR4X2 | c.377C>G p.T126S | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV56584455; called by muse, mutect2
- OR5H1 | c.808C>G p.Q270E | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as COSV100641736, COSV63403082; called by muse, mutect2, varscan2
- PCDHGA12 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.2); catalogued as rs758701539, COSV52761643; called by muse, mutect2, varscan2
- PCDHGA3 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.229); catalogued as COSV99530044; called by muse, mutect2, varscan2
- PCK1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60129313; called by muse, mutect2, varscan2
- PCLO | c.9773A>G p.E3258G | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61654242; called by muse, mutect2
- PKD1L1 | c.4582C>T p.P1528S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV56973161; called by muse, mutect2, varscan2
- RYR1 | c.8177A>G p.K2726R | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV62105081, COSV62112502; called by muse, mutect2
- SDK1 | c.4321G>A p.D1441N | Missense Mutation (SNP) | VAF 99/151 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.241); catalogued as rs368279674; called by muse, mutect2, varscan2
- TEKT4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs782309098, COSV54627012, COSV54628670; called by mutect2, varscan2
- TYR | c.1126C>G p.Q376E | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as CM930719, COSV54482161; called by muse, mutect2, varscan2
- XIAP | c.1184A>G p.E395G | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV63023254; called by muse, mutect2, varscan2
- ZFAND2B | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs1412019808, COSV54698696; called by muse, mutect2, varscan2
- H2AX | c.296dup p.G100Rfs*131 | Frame Shift Ins (INS) | VAF 54/229 reads (24%) | called by mutect2, pindel, varscan2
- VPS13D | c.11084A>G p.Y3695C | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLUL1 | c.9G>A p.P3= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1209650971, COSV58112964; called by muse, mutect2, varscan2
- CPSF7 | c.1287C>T p.S429= (on ENST00000394888 / NM_001136040.4; = p.S472= on NM_024811.4) | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV61212364; called by muse, mutect2, varscan2
- FRMD4A | c.2658C>T p.G886= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV62267788; called by muse, mutect2
- GATA3 | c.360G>A p.T120= | Silent (SNP) | VAF 95/247 reads (38%) | catalogued as COSV60521155, COSV60522900; called by muse, mutect2, varscan2
- IGDCC4 | c.2070G>A p.V690= | Silent (SNP) | VAF 60/150 reads (40%) | catalogued as COSV61538503; called by muse, varscan2
- IRF8 | c.759G>A p.P253= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs747312747, COSV51897709; called by muse, mutect2, varscan2
- MGRN1 | c.1446C>T p.G482= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as rs368148078; called by muse, mutect2, varscan2
- NFATC1 | c.2085C>T p.P695= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs773991020, COSV53705658; called by muse, mutect2, varscan2
- PBX2 | c.129G>T p.G43= | Silent (SNP) | VAF 34/105 reads (32%) | catalogued as rs779099117, COSV66709226, COSV66709233; called by muse, varscan2
- SLC20A2 | c.819G>A p.E273= | Silent (SNP) | VAF 119/280 reads (43%) | catalogued as COSV60605661; called by muse, mutect2, varscan2
- ZC3H4 | c.618C>T p.G206= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as rs774486510, COSV53415534; called by muse, mutect2, varscan2
- ZEB2 | c.3294A>G p.K1098= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV57962385; called by muse, mutect2, varscan2
